Surgical pathology report (de-identified scan), TCGA case TCGA-78-7152, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Prince Charles Hospital, specimen TCGA-78-7152-01A (Primary Tumor).

HISTORY

Right upper lobectomy.

MACROSCOPIC

Two specimens submitted.

1: The first specimen is labelled "right upper lobe" and consists of a right upper lobe of lung measuring 115 x 100 x 35 mm. A solid mass is palpable in the upper lateral segment of the lung (segment 2). The pleura overlying this mass appears puckered and there is an attached piece of pleura measuring approximately 120 mm in length. On sectioning of the lung a tumour measuring 28 x 25 x 40 mm is seen. It has a cream and grey-black cut surface. The margins of the tumour appear irregular. The tumour abuts the anterior pleura but is well clear of the posterior pleural surface. There is no gross bronchial involvement seen. The remaining lung tissue appears emphysematous. [1A, bronchial resection margins; 1B, parabronchial lymph nodes; 1C-1E, RS of tumour; 1F, uninvolved lung.]

2: The second specimen is labelled "No. 10 lymph node" and consists of two pieces of darkly pigmented tissue resembling a lymph node and measuring in aggregate 12 x 12 x 5 mm. [Wrapped and blocked in toto, 2A]

MICROSCOPIC

1: Sections show a well differentiated to moderately differentiated mucin-secreting adenocarcinoma with a predominant papillary and lepidic architecture. Centrally tumour acini infiltrate dense fibroelastotic scar tissue. The tumour abuts and focally invades into the overlying pleura. Definite vascular, lymphatic or perineural invasion is not identified. Adjacent lung parenchyma shows bullous emphysema and organising pneumonia. The bronchial resection margin is clear of malignancy and shows no evidence of squamous metaplasia or dysplasia. Peribronchial lymph nodes do not contain metastatic adenocarcinoma.

2: Sections show lymph nodes in which there is no evidence of malignancy.

SUMMARY

Right upper lobectomy and lymph node sampling:
Well to moderately differentiated adenocarcinoma, 40 mm in diameter.
Pleural invasion present.
No vascular, lymphatic or perineural invasion found.
No lymph node metastases.
Pathological stage T2 N0.

T-28000 M-81403 P1-03000

Source: NCI Genomic Data Commons file ce90014b-6858-4ba4-92c6-271c88843552 (TCGA-78-7152.4EE9AA80-A04B-4220-8657-0B05AF9DA97C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).